Somatic mutation profile of tumor specimen MP2PRT-PATJXU-TMP1-A (aliquot MP2PRT-PATJXU-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATJXU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.5 years (1,660 days).
Specimen MP2PRT-PATJXU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 089dda78-039d-462b-8c8d-094bfa27b714.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJXU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJXU-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d14d8f9-ece4-4b99-82bf-5d30b5a88219

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Del 1, 3'Flank 1, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844_845insCCC p.D281_R282insP | In Frame Ins (INS) | VAF 204/404 reads (50%) | hotspot (GDC flag); catalogued as COSV53688964; called by pindel, varscan2
- FMO1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770338150; called by muse, mutect2, varscan2
- IGKV3-15 | c.345del p.P115del | Frame Shift Del (DEL) | VAF 42/173 reads (24%) | catalogued as rs1362692308; called by mutect2, pindel*, varscan2
- MGAT4B | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 114/488 reads (23%) | catalogued as rs900685879; called by muse, mutect2, varscan2
- MYO18B | c.3473G>A p.R1158H | Missense Mutation (SNP) | VAF 158/550 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as rs759446365, COSV59139800; called by muse, mutect2, varscan2
- OR8D4 | c.628A>G p.T210A | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV58431074; called by muse, mutect2, varscan2
- CACNA1F | c.738dup p.V247Rfs*52 | Frame Shift Ins (INS) | VAF 117/313 reads (37%) | called by mutect2, pindel, varscan2
- CACNA1G | c.5099C>T p.S1700L | Missense Mutation (SNP) | VAF 117/358 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- EFNB1 | c.719T>C p.L240S | Missense Mutation (SNP) | VAF 189/364 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- PLCE1 | c.3880A>C p.N1294H | Missense Mutation (SNP) | VAF 105/373 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- SLC25A52 | c.880G>T p.G294C (on ENST00000672005; = p.G284C on NM_001034172.4) | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.120C>T p.H40= | Silent (SNP) | VAF 69/317 reads (22%) | catalogued as rs1221072372, COSV67208120; called by muse, mutect2, varscan2
- MTTP | c.2184G>A p.V728= | Silent (SNP) | VAF 84/247 reads (34%) | catalogued as COSV55508718; called by muse, mutect2, varscan2
- P3H2 | c.579G>A p.A193= | Silent (SNP) | VAF 105/404 reads (26%) | catalogued as rs377052077; called by muse, mutect2, varscan2
- PCDH17 | c.3033C>T p.L1011= | Silent (SNP) | VAF 114/420 reads (27%) | catalogued as rs1402581521, COSV64973420, COSV64979203; called by muse, mutect2, varscan2
- WDR20 | c.120C>T p.F40= | Silent (SNP) | VAF 127/531 reads (24%) | called by muse, mutect2, varscan2
- LCORL | chr4:17876712 G>A | 3'Flank (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
